Surgical pathology report (de-identified scan), TCGA case TCGA-JX-A5QV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Washington University, specimen TCGA-JX-A5QV-01A (Primary Tumor).

[page 1 of 4]
Patient Name: [REDACTED]
DOB: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

FINAL

Patient Name: [REDACTED]		Service: GYN	Accession #: [REDACTED]
Address: [REDACTED]		Location: [REDACTED]	Taken: [REDACTED]
Gender: F	MRN: [REDACTED]	Received: [REDACTED]	
	Hospital #: [REDACTED]	Accessioned: [REDACTED]	
	Patient Type: [REDACTED]	Reported: [REDACTED]	

DIAGNOSIS:

UTERUS, RADICAL HYSTERECTOMY

- CERVICAL SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, INVASIVE TO A DEPTH OF 14 MM (CERVICAL THICKNESS OF 15 MM, TUMOR WIDTH APPROXIMATELY 2 CM), WITH MULTIFOCAL LYMPHVASCULAR SPACE INVASION, WITHOUT PARAMETRIAL INVASION, RESECTION MARGINS NOT INVOLVED
- SECRETORY ENDOMETRIUM
- VAGINAL CUFF WITH NO EVIDENCE OF MALIGNANCY

VAGINA, RIGHT LATERAL MARGIN, EXCISION

- NO EVIDENCE OF MALIGNANCY

VAGINA, ADDITIONAL RIGHT MID VAGINAL MARGIN, EXCISION

- NO EVIDENCE OF MALIGNANCY

FALLOPIAN TUBES, BILATERAL, SALPINGECTOMY

- NO EVIDENCE OF MALIGNANCY

LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISIONAL BIOPSY

- NO EVIDENCE OF MALIGNANCY (3)

LYMPH NODES, LEFT OBTURATOR, EXCISIONAL BIOPSY

- NO EVIDENCE OF MALIGNANCY (3)

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISIONAL BIOPSY

- NO EVIDENCE OF MALIGNANCY (5)

LYMPH NODE, RIGHT OBTURATOR, EXCISIONAL BIOPSY

- MATURE ADIPOSE TISSUE, NO LYMPHOID TISSUE IDENTIFIED
- NO EVIDENCE OF MALIGNANCY

LYMPH NODE, RIGHT, PERIAORTIC, EXCISIONAL BIOPSY

- NO EVIDENCE OF MALIGNANCY (1)

LYMPH NODES, LEFT PERIAORTIC, EXCISIONAL BIOPSY

ICD-3
Carcinoma, squamous cell,
K05.811/3
Site: Cervix NOS C53.9
4/3 3/28/13

[page 2 of 4]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

- NO EVIDENCE OF MALIGNANCY (2)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out by:

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'uterus, cervix,' is a 197 gram specimen consisting of a uterus with an attached cervix (fundus/ectocervix: 11 cm; cornu to cornu: 5.7; anterior-posterior: 5.3 cm). Parametrial tissue is inked black. Opened to show a 1.7 x 1.5 cm cervical lesion invading to a depth of 1.4 cm grossly. The lesion extends up to the right parametrial inked margin. Small portion of tumor and normal for study. Rest for permanents. Shown to surgeon," t

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year old woman with cervical cancer. Operative procedure: Radical hysterectomy, bilateral salpingo-oophorectomy, and pelvic lymph node dissection.

Specimen(s) Received:

- A: LEFT EXTERNAL ILIAC LYMPH NODE
- B: LEFT OBTURATOR LYMPH NODE
- C: RIGHT EXTERNAL ILIAC LYMPH NODE
- D: RIGHT OBTURATOR LYMPH NODE
- E: RIGHT PERIAORTIC LYMPH NODE
- F: LEFT PERIAORTIC LYMPH NODE
- G: RIGHT FALLOPIAN TUBE
- H: LEFT FALLOPIAN TUBE
- I: UTERUS AND CERVIX
- J: RIGHT LATERAL VAGINAL MARGIN
- K: ADDITIONAL RIGHT MID-VAGINAL MARGIN

Gross Description:

The specimens are received in 11 formalin-filled containers, each labeled with the patient's name "[REDACTED]". The first specimen is labeled "left external iliac lymph node." It consists of multiple fragments of fibroadipose tissue that measure, in aggregate, 4 x 2 x 2 cm. On dissecting, three lymph nodes ranging from 0.4 to 1.5 cm are identified; sections of these lymph nodes show unremarkable areas. Labeled A1 - two lymph nodes; A2 - one lymph node. Jar 1.

The second specimen is labeled "left obturator lymph node." It consists of several fragments of fibroadipose tissue that measure, in aggregate, 2.5 x 2.0 x 1.0 cm. On sectioning and dissection, three lymph nodes ranging from 0.5 to 1.5 cm in diameter are identified; sections of these lymph nodes show largely to be composed of adipose tissue. Bisected. Labeled B1 - two lymph nodes; B2 - one lymph node. Jar 0.

The third specimen is labeled "right external iliac lymph node." It consists of several fragments of fibroadipose tissue that measure, in aggregate, 5 x 3 x 1.5 cm. On dissecting, two lymph nodes ranging from 1.5 cm to 3 cm in maximal

[page 3 of 4]
Patient Name: [REDACTED]

SURGICAL PATHOLOGY REPORT

dimensions are identified; sections of the lymph nodes show largely to be composed of adipose tissue. Labeled C1 - one lymph node (not bisected); C2 - second lymph node (3 cm) bisected. Jar 1.

The fourth specimen is labeled "right obturator lymph node." It consists of a single lymph node with attached adipose tissue that measures 0.5 x 0.2 x 0.2 cm. Sectioning shows putative lymph nodal tissue. Labeled D1. Jar 0.

The fifth specimen is labeled "right periaortic lymph node." It consists of a single lymph node measuring 4.5 x 2.5 x 1.0 cm in its maximal dimensions with attached fibroadipose tissue. On sectioning the node is shown to be composed largely of adipose tissue. Divided into two halves. Bisected. Labeled E1 and E2. Jar 1.

The sixth specimen is labeled "left periaortic lymph node." It consists of two lymph nodes, ranging from 0.7 to 0.9 cm in diameter. Sections show unremarkable areas. Labeled F1 - two lymph nodes (bisected). Jar 0.

The seventh specimen is labeled "right fallopian tube." It consists of the fallopian tube with its fimbriated end, measuring 6 cm in length with a diameter ranging from 0.4 to 1.0 cm. A metallic clip is found in its proximal portion (1.5 x 0.4 x 0.4 cm). Sections show compacted mucosal folds and a pinpoint lumen. Labeled G1. Jar 1.

The eighth specimen is labeled "left fallopian tube." It consists of the fallopian tube measuring 6 cm in length with a diameter ranging from 0.5 to 1.0 cm. Sectioning shows compacted mucosal folds and a pinpoint lumen. No focal lesions are noted. Labeled H1. Jar 1.

The ninth specimen is labeled "uterus, cervix." It consists of a uterus with attached bilateral parametria as described in the intraoperative non-microscopic consultation. The ectocervix shows an excavating lesion present mainly along the right half of the specimen, measuring 2.5 x 2 cm. On opening and further sectioning, a homogenous yellow-white fleshy tumor is present beneath the ulcer involving the stroma of the cervical canal and extending into adjacent parametrial tissue, measuring 1.7 x 1.5 x 1.5 cm. The tumor appears to originate in the lower part of the endocervical canal but shows significant extension into underlying right half of the cervix. Tumor is present 1.5 cm from the internal cervical os. The endometrial cavity measures 4 x 2 cm and shows no focal lesions. The endometrium measures 0.4 cm in thickness with a myometrial thickness of 2.5 cm. No other focal lesions are noted in the endometrium or the myometrium. The anterior vaginal cuff measures 6 x 2 x 2 cm. The posterior vaginal cuff measures 6 x 1.5 cm. The tumor extends close (0.2 cm) to the resected vaginal margin but does not appear to extend to it. Labeled I1 - anterior resected margin of vaginal cuff; I2 - posterior resected margin of vaginal cuff (both shave margins); I3 to I9 - tumor, involving right anterior cervix and parametrium; I10 to I15 - tumor with posterior portion of cervix and parametrium; I16, I17 - anterior endomyometrium; I18 - posterior endomyometrium. Jar 2.

The tenth specimen is labeled "right lateral vaginal margin." It consists of a single irregular fibroadipose tissue fragment, that is partially covered by vaginal mucosa, which is distorted and irregular, measuring 3 x 1 x 0.8 cm. No orientation is provided. Specimen inking is not possible due to the distorted nature of the specimen and the lack of directions. Labeled J1 to J3. Jar 0.

The 11th specimen is labeled "additional right mid vaginal margin." It consists of a portion of soft tissue that is partially mucosal covered, that measures 2.5 x 1.5 x 1.0 cm. Multiple sutures are attached to the opposite-appearing resected surface of the specimen. These are removed. No orientation is provided for the specimen. The surfaces opposite of the mucosa are inked in blue. Sectioned. Labeled K1 to K2. Jar 0.

SYNOPTIC REPORTING FORM FOR UTERINE CERVICAL NEOPLASMS

HISTOPATHOLOGIC TYPE

Squamous cell carcinoma, Keratinizing

Squamous cell carcinoma, Basaloid *upon review by TSS, no basaloid differentiation, per TSS.*

TUMOR SIZE

The maximum depth of the tumor invasion is 1.4 cm

The breadth (maximum horizontal dimension) of the tumor is 2 cm

The total thickness of the cervix is 1.5 cm

[page 4 of 4]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

LYMPHATIC INVASION

Lymphatic invasion by tumor is identified but is focal

HISTOPATHOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

The tumor does not invade through the entire thickness of the cervix to involve contiguous parametrial tissues.

VAGINAL INVOLVEMENT

The tumor does not involve the vagina

TUMOR METASTASIS

Metastasis of tumor to regional lymph nodes is absent

The total number of metastatically-involved lymph nodes is 0

The total number of lymph nodes examined is 14

Extracapsular extension of metastatic tumor through the lymph node capsule is not applicable; no metastasis seen

PRIMARY TUMOR (T)

Clinically visible lesion 4.0 cm or less in greatest dimension (T1b1/IB1)

REGIONAL LYMPH NODES

No regional lymph node metastasis (N0)

DISTANT METASTASIS

No distant metastasis (M0)

STAGE GROUPING

The final stage of the tumor is Stage IB1 T1b1/N0/M0

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

—

—

—

Source: NCI Genomic Data Commons file f8eff017-4983-47f5-8831-e6113ad2a0e2 (TCGA-JX-A5QV.6C4DBD4D-8F4E-4680-AE60-1AFE2BF72732.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).